Somatic mutation profile of tumor specimen TCGA-LN-A4MQ-01A (aliquot TCGA-LN-A4MQ-01A-11D-A28B-09) from TCGA case TCGA-LN-A4MQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 46.5 years (16,990 days).
Specimen TCGA-LN-A4MQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d880dc7b-4bb1-42de-96a6-fa9701cdd117.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4MQ-10A (Blood Derived Normal), aliquot TCGA-LN-A4MQ-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d491c90-3d33-4b32-9dd2-36946aaf80ab

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 18, Nonsense Mutation 5, Frame Shift Ins 2, Translation Start Site 1, Frame Shift Del 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 57/166 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.713_715del p.C238_N239delinsY | In Frame Del (DEL) | VAF 50/78 reads (64%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ANKS6 | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62049794; called by muse, mutect2
- ARHGAP5 | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as rs372981423; called by muse, varscan2
- CNGA1 | c.1729C>T p.L577F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1352342372; called by muse, mutect2
- FAM135B | c.4088G>A p.R1363Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52720945; called by muse, mutect2, varscan2
- GRM3 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.371); catalogued as COSV64468213; called by muse, mutect2, varscan2
- MMP16 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs753769443, COSV54149337; called by muse, mutect2, varscan2
- MST1R | c.2600G>C p.S867T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs761033628; called by muse, mutect2, varscan2
- NTN3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs749265175, COSV99564675; called by muse, mutect2, varscan2
- PLGLB2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV63948126; called by mutect2, varscan2
- PREX1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64247891; called by muse, mutect2
- PTEN | c.787A>T p.K263* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as rs1554825254, COSV64298269; called by muse, mutect2, varscan2
- PTGIS | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs745642215, COSV54836304; called by muse, mutect2, varscan2
- RHBDF2 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs889709554; called by muse, mutect2, varscan2
- SDK2 | c.4785C>G p.Y1595* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as rs141328074; called by muse, mutect2, varscan2
- SKOR1 | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV58247299; called by muse, mutect2, varscan2
- SMARCC2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV99911121; called by muse, mutect2, varscan2
- STOX2 | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408287; called by muse, mutect2, varscan2
- TOGARAM2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768497249; called by muse, mutect2, varscan2
- TTLL7 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1425599487; called by muse, mutect2, varscan2
- TTN | c.20531G>C p.R6844T (on ENST00000591111; = p.R5917T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | PolyPhen benign (0.013); catalogued as COSV59928538; called by muse, mutect2
- UROC1 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201269614; called by muse, mutect2, varscan2
- USP34 | c.6551A>G p.Y2184C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs749963447; called by muse, mutect2, varscan2
- ZNF267 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs757192362, COSV56250564; called by muse, mutect2, varscan2
- ZNF77 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs1476631311; called by muse, mutect2
- ZNF84 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV59654241; called by muse, mutect2, varscan2
- ADAM28 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ARF4 | c.281_282insATCG p.S94Rfs*6 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ATG2B | c.6040A>G p.T2014A | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CA3 | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKAL1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX4 | c.1762T>A p.F588I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKK | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- FUT8 | c.1168T>A p.F390I (on ENST00000360689 / NM_001371534.1; = p.F227I on NM_004480.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- HCAR2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HRH1 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IGKV3D-7 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2
- KRTAP9-8 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.973); called by muse, mutect2
- MDC1 | c.1177A>G p.K393E | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- MTMR1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NEK5 | c.1741T>A p.F581I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- NIPBL | c.8074T>A p.S2692T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NLRP11 | c.2642G>A p.C881Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NUMA1 | c.2165dup p.R723Afs*16 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- OR10H1 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- PANK4 | c.1952G>T p.C651F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- PDE4DIP | c.3467C>T p.S1156F | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PPP2R3B | c.755A>G p.K252R | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKDC | c.9005A>G p.Y3002C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- RB1 | c.1632del p.E545Kfs*2 | Frame Shift Del (DEL) | VAF 28/49 reads (57%) | called by mutect2, pindel, varscan2
- RNF216 | c.1378C>T p.R460* (on ENST00000425013 / NM_207116.3; = p.R517* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- SETX | c.5737G>C p.D1913H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SHANK3 | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMYD1 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- STOX2 | c.2033G>C p.G678A | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SUMO4 | c.32A>T p.K11M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TAF1A | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS41 | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ZNF415 | c.104T>C p.M35T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARRDC1 | c.603G>A p.V201= | Silent (SNP) | VAF 54/77 reads (70%) | called by muse, mutect2, varscan2
- CDC5L | c.1689G>A p.P563= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs375237261; called by muse, mutect2, varscan2
- CYSTM1 | c.293G>A p.*98= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs370523896; called by muse, mutect2, varscan2
- EPB41L1 | c.1908C>T p.F636= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- IQSEC1 | c.855G>T p.L285= | Silent (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- IRAK2 | c.696G>A p.K232= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV56534908; called by muse, mutect2, varscan2
- LZTS3 | c.327C>T p.T109= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100232272; called by muse, mutect2, varscan2
- NXPH3 | c.195C>T p.L65= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV60872339; called by muse, mutect2, varscan2
- OR2B6 | c.753T>C p.F251= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs1206523127; called by muse, mutect2
- PCDHB14 | c.1476G>A p.P492= | Silent (SNP) | VAF 12/179 reads (7%) | catalogued as rs782655623; called by muse, mutect2
- PCDHGA5 | c.1657C>T p.L553= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- PMP22 | c.453C>A p.V151= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- RARG | c.117C>T p.F39= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs556025298; called by muse, mutect2, varscan2
- RYR2 | c.6912T>C p.F2304= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV63718930; called by muse, mutect2, varscan2
- TSC2 | c.2655C>T p.I885= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs1060504116, COSV54764130; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF394 | c.168T>G p.A56= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- ZNF431 | c.990C>T p.T330= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1187663909; called by muse, mutect2, varscan2
- ZNF701 | c.939A>T p.V313= (on ENST00000301093; = p.V247= on NM_018260.3) | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- SPACA6 | chr19:51692653 A>G | 5'Flank (SNP) | VAF 48/194 reads (25%) | called by muse, mutect2, varscan2
